Somatic mutation profile of tumor specimen ALCH-B3H0-TTP1-A (aliquot ALCH-B3H0-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3H0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.2 years (27,845 days).
Specimen ALCH-B3H0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c0be483-921f-46db-8189-9e53dd1b2e52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3H0-NB1-A (Blood Derived Normal), aliquot ALCH-B3H0-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad7bde43-baea-4cfd-ada9-a27406f8bda7

The open-access MAF lists 250 somatic variants for this specimen: 174 protein-altering or splice-affecting, 44 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 44, Intron 13, Nonsense Mutation 10, RNA 8, Splice Site 7, 3'UTR 5, Frame Shift Del 3, 5'UTR 3, Splice Region 2, 5'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAH | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs779040832, CM940753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 138/541 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-2A>C p.X332_splice | Splice Site (SNP) | VAF 35/173 reads (20%) | hotspot (GDC flag); catalogued as CS159286, COSV52692098, COSV52692518, COSV53122371; called by muse, mutect2, varscan2
- ADGRG4 | c.1438G>T p.V480L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54956928; called by muse, mutect2, varscan2
- ADGRV1 | c.12517G>C p.A4173P | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67982658; called by muse, mutect2, varscan2
- AGL | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 35/417 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs762935611, COSV54054571; ClinVar: uncertain significance; called by muse, mutect2
- ANK1 | c.2797G>T p.G933C | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55884265; called by muse, mutect2, varscan2
- ARID1A | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 64/188 reads (34%) | catalogued as COSV61383718; called by muse, mutect2, varscan2
- BICD1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756217437, COSV99862716; called by muse, mutect2, varscan2
- BMP10 | c.1097C>G p.P366R | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104401864; called by muse, mutect2, varscan2
- C2 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as COSV54959109; called by muse, mutect2, varscan2
- CACNA1E | c.6664G>T p.A2222S (on ENST00000367573 / NM_001205293.3; = p.A2179S on NM_000721.4) | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs369634310; called by muse, mutect2, varscan2
- CDC42BPA | c.2995G>T p.G999* (on ENST00000334218 / NM_001366019.2; = p.G986* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/243 reads (11%) | catalogued as COSV100503346; called by muse, mutect2, varscan2
- CDH18 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.943); catalogued as rs575682286; called by muse, varscan2
- CDH9 | c.2183G>T p.S728I | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99148626; called by muse, mutect2
- CELA2A | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs555930156, COSV62747683; called by muse, mutect2, varscan2
- CFAP61 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1300114881; called by muse, mutect2, varscan2
- CLDN17 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769339338, COSV54525243; called by muse, mutect2, varscan2
- CLIP1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1409246321; called by muse, mutect2, varscan2
- CYTH4 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50631580; called by muse, mutect2, varscan2
- DMPK | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV52180219; called by muse, mutect2, varscan2
- ELMO1 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs762877369, COSV60294903; called by muse, mutect2, varscan2
- FAM90A1 | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 36/588 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.26); catalogued as rs894241491; called by muse, mutect2
- GFUS | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1365955470; called by muse, mutect2, varscan2
- HPDL | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs761815101; called by muse, mutect2, varscan2
- KPRP | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.357); catalogued as rs755668740, COSV64222581; called by muse, mutect2, varscan2
- LRRN4 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV101125548; called by muse, mutect2, varscan2
- MAP4K5 | c.379-1G>T p.X127_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as rs1396923396; called by muse, mutect2, varscan2
- MPHOSPH10 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 39/322 reads (12%) | catalogued as COSV99731216; called by muse, mutect2, varscan2
- MRTFA | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as rs753676894; called by muse, mutect2, varscan2
- MTCL1 | c.3588G>C p.L1196F (on ENST00000306329 / NM_001378206.1; = p.L877F on NM_015210.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV60403584; called by muse, mutect2, varscan2
- MUC17 | c.8604T>A p.S2868R | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV60299671; called by muse, mutect2, varscan2
- NBAS | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104386095, COSV99871290; called by muse, mutect2, varscan2
- NOTO | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1227964419; called by muse, mutect2, varscan2
- NPAP1 | c.2419G>T p.V807L | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.188); catalogued as COSV61504697; called by muse, mutect2, varscan2
- NRXN1 | c.634G>C p.G212R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101278397; called by muse, mutect2, varscan2
- NYAP2 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as COSV56000093; called by muse, mutect2, varscan2
- OLFML2A | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140519605; called by mutect2, varscan2
- OR5B17 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs1287872485; called by muse, mutect2, varscan2
- PABPC3 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs769964946; called by muse, varscan2
- PIK3CB | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs750375278; called by muse, mutect2
- PLCL1 | c.3105+2T>C p.X1035_splice | Splice Site (SNP) | VAF 9/81 reads (11%) | catalogued as rs1017245685, COSV101407253; called by muse, mutect2, varscan2
- PMVK | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs200157729, COSV63786006; called by muse, mutect2, varscan2
- PRIM2 | c.693+7A>G | Splice Region (SNP) | VAF 24/105 reads (23%) | catalogued as rs769627943; called by muse, mutect2, varscan2
- R3HDML | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53835506; called by muse, mutect2, varscan2
- RABEPK | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as rs746870481, COSV52335942, COSV52336542; called by muse, mutect2, varscan2
- RXRG | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104417072; called by muse, mutect2, varscan2
- RYR2 | c.2545G>C p.D849H | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as COSV104419366; called by muse, mutect2, varscan2
- SETD2 | c.4408C>T p.P1470S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57435499, COSV57450205; called by muse, varscan2
- SLFN11 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57698926; called by muse, mutect2
- STARD3NL | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV50518147; called by muse, mutect2, varscan2
- SYNRG | c.3700A>G p.M1234V | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.959); catalogued as rs1003225090; called by muse, varscan2
- THEM5 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs768216646; called by muse, mutect2, varscan2
- TPCN1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59239792; called by muse, mutect2, varscan2
- TTN | c.43012C>T p.P14338S (on ENST00000591111; = p.P6914S on NM_003319.4) | Missense Mutation (SNP) | VAF 94/413 reads (23%) | PolyPhen probably damaging (0.998); catalogued as rs1473380697; called by muse, mutect2, varscan2
- VSIG4 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV66074156; called by muse, mutect2, varscan2
- ZGRF1 | c.4834G>A p.V1612I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs781536904; called by muse, mutect2, varscan2
- ZNF528 | c.1316G>A p.C439Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748159086; called by muse, mutect2, varscan2
- ZNF556 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs974932069, COSV56913058; called by muse, mutect2, varscan2
- ZNF578 | c.1328C>G p.A443G | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1458814836; called by muse, mutect2, varscan2
- ZNF586 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs557538085, COSV66972344; called by muse, mutect2, varscan2
- ZSCAN1 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56604954; called by muse, mutect2, varscan2
- ZYG11A | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs574301787, COSV65293187; called by muse, mutect2, varscan2
- ABCC11 | c.3400G>T p.G1134W | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- ABHD12 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 30/551 reads (5%) | called by muse, mutect2
- ADAMTS6 | c.1588A>C p.T530P | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGB | c.3911C>T p.S1304F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADGRB3 | c.2683C>A p.L895I | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AL117348.2 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AMTN | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); called by muse, mutect2
- ANAPC5 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ANKRD30B | c.2302G>A p.G768S | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.931); called by muse, mutect2
- ANO5 | c.776del p.K259Sfs*31 | Frame Shift Del (DEL) | VAF 36/315 reads (11%) | called by mutect2, pindel, varscan2
- ARID2 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ASL | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 87/464 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP7B | c.4172A>T p.H1391L | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B4 | c.2454T>A p.N818K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1GALT1C1L | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- C1QL1 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARS2 | c.23_38del p.P8Rfs*53 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- CC2D2A | c.4677C>T p.F1559= | Splice Region (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- CCDC150 | c.2606G>T p.R869L | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC91 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- CCT8L2 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDKN1C | c.742G>T p.G248* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- CEP76 | c.1697T>G p.F566C | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CFAP69 | c.198A>T p.K66N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CHRNA5 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.5429T>A p.L1810Q | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- COP1 | c.1897C>G p.L633V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CPLANE1 | c.9148+1G>C p.X3050_splice | Splice Site (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- CPT1A | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWF19L2 | c.2101C>G p.P701A | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CYB5R4 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.826); called by muse, mutect2
- DCDC1 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DNAH6 | c.4621C>G p.L1541V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- EGFR | c.3518A>T p.Q1173L | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ERBB3 | c.1680G>T p.E560D | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FAT1 | c.9413_9414del p.T3138Rfs*28 | Frame Shift Del (DEL) | VAF 43/159 reads (27%) | called by pindel, varscan2
- GOT2 | c.1183A>G p.I395V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERPUD2 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- IGHG3 | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.194); called by muse, mutect2
- IGHV3OR16-9 | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 70/504 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.404); called by muse, varscan2
- KCNH8 | c.2487T>G p.F829L | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- KCNK4 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ5 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- KLHL17 | c.1110C>A p.H370Q | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KRT19 | c.593C>G p.T198S | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- LRBA | c.5164T>A p.F1722I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- MAGEL2 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP3K7 | c.867+1del p.X289_splice | Splice Site (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- MAP4K5 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MATN2 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCM2 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDC1 | c.3827C>A p.S1276Y | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MYH7B | c.1150G>T p.G384C | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO15A | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- NT5DC3 | c.1094A>T p.Y365F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OGDHL | c.2374G>C p.D792H | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR10A3 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- OR7D2 | c.920G>T p.R307M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.538); called by muse, mutect2
- PAX2 | c.1168G>A p.A390T (on ENST00000428433 / NM_003987.5; = p.A367T on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- PCDH17 | c.2190C>A p.C730* | Nonsense Mutation (SNP) | VAF 47/281 reads (17%) | called by muse, mutect2, varscan2
- PDHA1 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHF10 | c.1217A>C p.N406T | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PHLPP2 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- PKDREJ | c.255dup p.R86Afs*211 | Frame Shift Ins (INS) | VAF 26/127 reads (20%) | called by mutect2, pindel, varscan2
- PLG | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNPT1 | c.823A>T p.K275* | Nonsense Mutation (SNP) | VAF 64/195 reads (33%) | called by muse, mutect2, varscan2
- POLR3F | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PROKR1 | c.682T>A p.Y228N | Missense Mutation (SNP) | VAF 105/375 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PSTPIP1 | c.176A>T p.Q59L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); called by muse, mutect2
- R3HDM1 | c.1475-1G>T p.X492_splice | Splice Site (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- R3HDM1 | c.2260A>G p.M754V | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEF1 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASGRF1 | c.2630C>G p.P877R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.224); called by muse, mutect2
- RIMS2 | c.2996G>C p.S999T (on ENST00000666250 / NM_001348490.2; = p.S807T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- RNF213 | c.4402G>T p.A1468S | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RTL9 | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDR16C5 | c.711-1G>T p.X237_splice | Splice Site (SNP) | VAF 45/350 reads (13%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.5098C>T p.P1700S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- SKOR2 | c.2139C>G p.H713Q | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- SLC15A5 | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- SLITRK2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SMARCA1 | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC3 | c.3160A>G p.T1054A | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SOAT1 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPON2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SYNE1 | c.21270G>T p.Q7090H (on ENST00000367255 / NM_182961.4; = p.Q7019H on NM_033071.3) | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SYNE1 | c.14144G>T p.G4715V (on ENST00000367255 / NM_182961.4; = p.G4644V on NM_033071.3) | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2
- TENM1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TGM7 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TMBIM6 | c.216G>C p.M72I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.119); called by muse, mutect2
- TMEM38A | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TMEM50B | c.50A>T p.D17V | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- TMOD1 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TREM1 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- TTN | c.52356G>T p.Q17452H (on ENST00000591111; = p.Q10028H on NM_003319.4) | Missense Mutation (SNP) | VAF 44/254 reads (17%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UBQLN3 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- UNC5B | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- USP28 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP34 | c.4777A>T p.S1593C | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASHC4 | c.491A>G p.Q164R | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZAN | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 69/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF236 | c.4936C>G p.P1646A | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF253 | c.183_184insT p.P62Sfs*8 | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | called by mutect2, pindel, varscan2
- ZNF283 | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF33A | c.1745G>T p.C582F (on ENST00000458705 / NM_006974.3; = p.C583F on NM_006954.2) | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF419 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- ZNF530 | c.1510A>T p.T504S | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF556 | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by mutect2, varscan2
- ZNF679 | c.817T>A p.C273S | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ZNF717 | c.2695G>T p.V899L | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF773 | c.86G>A p.W29* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- ADGRB1 | c.1290G>T p.R430= | Silent (SNP) | VAF 34/258 reads (13%) | called by muse, mutect2, varscan2
- BCAN | c.861G>T p.T287= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- C9orf131 | c.1677T>G p.S559= | Silent (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- CACNA1B | c.2526C>T p.P842= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs1213653589; called by muse, mutect2
- CCDC183 | c.894C>A p.G298= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as COSV61034096, COSV61034804; called by muse, mutect2, varscan2
- CCDC8 | c.45G>A p.R15= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- CDH10 | c.1168C>T p.L390= | Silent (SNP) | VAF 9/236 reads (4%) | catalogued as COSV52577588, COSV52600832; called by muse, mutect2
- DACT1 | c.1470T>C p.P490= | Silent (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- DEDD2 | c.228G>A p.G76= | Silent (SNP) | VAF 70/238 reads (29%) | called by muse, mutect2, varscan2
- DOP1B | c.3144C>T p.S1048= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs1293347604; called by muse, mutect2, varscan2
- DSG3 | c.2940G>A p.T980= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs768325351; called by muse, mutect2, varscan2
- EEF1A1 | c.495G>A p.K165= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2, varscan2
- ENOX1 | c.718C>A p.R240= | Silent (SNP) | VAF 16/283 reads (6%) | called by muse, mutect2
- EVI2B | c.597T>C p.N199= | Silent (SNP) | VAF 28/229 reads (12%) | called by muse, mutect2, varscan2
- EYA4 | c.201G>A p.G67= | Silent (SNP) | VAF 41/335 reads (12%) | catalogued as rs183101904; called by muse, mutect2, varscan2
- FASLG | c.417A>G p.E139= | Silent (SNP) | VAF 32/444 reads (7%) | catalogued as rs780093284, COSV100390566; called by muse, mutect2
- FCRL1 | c.588G>T p.L196= | Silent (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- FSCB | c.990T>G p.P330= | Silent (SNP) | VAF 37/154 reads (24%) | called by muse, mutect2, varscan2
- GDF9 | c.1251G>A p.P417= | Silent (SNP) | VAF 64/263 reads (24%) | catalogued as rs779083274, COSV51526680; called by muse, mutect2, varscan2
- GTF3A | c.531C>T p.S177= | Silent (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- GTSE1 | c.1179C>T p.S393= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs774728029; called by muse, mutect2, varscan2
- HIGD2A | c.267G>T p.T89= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV51257560; called by muse, mutect2, varscan2
- HNRNPD | c.69G>T p.A23= | Silent (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- KRTAP10-10 | c.156C>T p.C52= | Silent (SNP) | VAF 35/157 reads (22%) | called by muse, mutect2, varscan2
- LAMP5 | c.27C>A p.P9= | Silent (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- LSM1 | c.39C>T p.D13= | Silent (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- MEX3B | c.177G>T p.P59= | Silent (SNP) | VAF 16/163 reads (10%) | catalogued as rs1350131610; called by muse, mutect2
- MYO1G | c.2982G>A p.E994= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- NLRP11 | c.2253G>C p.L751= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as COSV64088874; called by muse, mutect2, varscan2
- NLRP3 | c.1314C>A p.T438= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- NOS1 | c.1881C>T p.S627= | Silent (SNP) | VAF 35/172 reads (20%) | called by muse, mutect2, varscan2
- OR2D2 | c.153T>A p.V51= | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- PCDH10 | c.1926C>A p.R642= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2
- PCGF1 | c.21C>A p.G7= | Silent (SNP) | VAF 45/262 reads (17%) | called by muse, mutect2, varscan2
- POLI | c.1194G>A p.G398= | Silent (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- RNF182 | c.243G>T p.L81= | Silent (SNP) | VAF 34/314 reads (11%) | called by muse, mutect2
- SIGLEC11 | c.1437C>A p.A479= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- STYXL2 | c.1683G>A p.L561= | Silent (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
- TP53BP2 | c.1164G>A p.E388= (on ENST00000343537 / NM_001031685.3; = p.E259= on NM_005426.2) | Silent (SNP) | VAF 27/275 reads (10%) | catalogued as COSV59071294; called by muse, mutect2
- TRIM46 | c.1395G>A p.E465= | Silent (SNP) | VAF 8/260 reads (3%) | called by muse, mutect2
- TRIML1 | c.189G>T p.P63= | Silent (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- UNC5D | c.1608C>T p.L536= | Silent (SNP) | VAF 29/200 reads (15%) | called by muse, mutect2, varscan2
- ZNF577 | c.876C>T p.H292= | Silent (SNP) | VAF 35/147 reads (24%) | called by muse, mutect2, varscan2
- ZNF835 | c.1212G>T p.S404= | Silent (SNP) | VAF 40/183 reads (22%) | called by muse, mutect2, varscan2
- A1BG | c.70+28G>A | Intron (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- AC073310.1 | n.761G>C | RNA (SNP) | VAF 32/138 reads (23%) | called by muse, varscan2
- ADAM6 | n.920A>T | RNA (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2, varscan2
- ADGRE4P | n.1779C>T | RNA (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- AFF3 | c.54-2606T>C | Intron (SNP) | VAF 40/297 reads (13%) | called by muse, mutect2, varscan2
- AHRR | c.442-1410G>A | Intron (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- ALKBH6 | c.-145G>A | 5'UTR (SNP) | VAF 30/124 reads (24%) | catalogued as rs762105505, COSV53325183; called by muse, mutect2, varscan2
- ANKRD20A5P | n.220G>T | RNA (SNP) | VAF 21/254 reads (8%) | catalogued as rs576772339; called by muse, mutect2
- BNIP3L | c.-53C>T | 5'UTR (SNP) | VAF 34/259 reads (13%) | catalogued as rs541391620; called by muse, mutect2, varscan2
- CASR | c.1378-6140C>T | Intron (SNP) | VAF 114/438 reads (26%) | catalogued as rs1553768122; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC162P | n.2426G>T | RNA (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- CD1C | c.*19C>T | 3'UTR (SNP) | VAF 20/184 reads (11%) | catalogued as rs755841801, COSV100939349; called by muse, mutect2, varscan2
- CEP170P1 | n.4462C>A | RNA (SNP) | VAF 21/177 reads (12%) | called by muse, mutect2, varscan2
- DAP | c.*101G>T | 3'UTR (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- DYNC1LI1 | c.220+3717C>A | Intron (SNP) | VAF 5/55 reads (9%) | catalogued as rs974796946; called by muse, varscan2
- EML3 | c.2488-40G>C | Intron (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- G6PC3 | c.*238C>T | 3'UTR (SNP) | VAF 22/121 reads (18%) | catalogued as rs764145183; called by muse, mutect2, varscan2
- KLRA1P | n.335A>G | RNA (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- LCLAT1 | c.743-34062G>C | Intron (SNP) | VAF 34/202 reads (17%) | called by muse, varscan2
- LINC01387 | n.307G>T | RNA (SNP) | VAF 72/262 reads (27%) | called by muse, mutect2, varscan2
- LYPLA1 | c.-1T>C | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- MUTYH | c.453+24G>T | Intron (SNP) | VAF 121/367 reads (33%) | called by muse, mutect2, varscan2
- NFU1 | c.166+1951G>T | Intron (SNP) | VAF 18/112 reads (16%) | catalogued as COSV58005926; called by muse, mutect2, varscan2
- OBSCN | c.989-19C>T | Intron (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- PRPF18 | c.66+4678G>T | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- PSMD9 | c.*4T>G | 3'UTR (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- RABGAP1L | c.2026-978T>A | Intron (SNP) | VAF 44/245 reads (18%) | called by muse, mutect2, varscan2
- RHBG | c.1112+70G>T | Intron (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- RNF170 | c.*2498_*2500del | 3'UTR (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- RPL37AP1 | chr20:44462122 C>A | 3'Flank (SNP) | VAF 51/188 reads (27%) | catalogued as rs1464628141; called by muse, mutect2, varscan2
- VPS16 | chr20:2840722 C>T | 5'Flank (SNP) | VAF 58/300 reads (19%) | called by muse, mutect2, varscan2
- WWC2 | chr4:183098473 G>T | 5'Flank (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
